Somatic mutation profile of tumor specimen C3L-07966-01 (aliquot CPT0479640009) from CPTAC case C3L-07966, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 64.6 years (23,611 days).
Specimen C3L-07966-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b18d22cd-f761-40dd-a245-1b69a57458d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07966-31 (Blood Derived Normal), aliquot CPT0479700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8d0872-c9ff-4f51-9e39-754218da78e1

The open-access MAF lists 330 somatic variants for this specimen: 214 protein-altering or splice-affecting, 102 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 102, Intron 8, Nonsense Mutation 8, Splice Region 4, RNA 2, 3'UTR 2, 5'Flank 1, Splice Site 1, 5'UTR 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 232/420 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 97/175 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM983500, COSV64289544, COSV64299563; called by muse, mutect2, varscan2
- AL592490.1 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 306/614 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425764; called by muse, mutect2, varscan2
- ALOXE3 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 156/413 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs564036985; called by muse, mutect2, varscan2
- APOBEC3G | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 147/461 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV68470019; called by muse, mutect2, varscan2
- BCDIN3D | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs138122105; called by muse, mutect2, varscan2
- BCORL1 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 198/264 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1199456475, COSV54391416; called by muse, varscan2
- BRINP3 | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 123/451 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV66532835; called by muse, mutect2, varscan2
- C1QTNF9B | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 150/1283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221459808, COSV101158611; called by muse, mutect2, varscan2
- C2CD2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 130/358 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV100298145; called by muse, mutect2, varscan2
- C4orf17 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV58513238; called by muse, mutect2, varscan2
- C4orf17 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV56745038; called by muse, mutect2, varscan2
- CACNA1C | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 234/600 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs868696148; called by muse, mutect2, varscan2
- CASR | c.2136C>A p.F712L (on ENST00000490131; = p.F789L on NM_000388.4) | Missense Mutation (SNP) | VAF 186/277 reads (67%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as CD109034, COSV104407020; called by muse, mutect2, varscan2
- CCDC144A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100501938; called by muse, mutect2, varscan2
- CCPG1 | c.1817dup p.N606Kfs*12 | Frame Shift Ins (INS) | VAF 115/377 reads (31%) | catalogued as rs1428090013; called by mutect2, pindel, varscan2
- CD244 | c.796G>A p.E266K (on ENST00000368033 / NM_001166663.2; = p.E261K on NM_016382.4) | Missense Mutation (SNP) | VAF 241/476 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV59239979; called by muse, mutect2, varscan2
- CDC25C | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as COSV100086702; called by muse, mutect2, varscan2
- CHAT | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 106/182 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100340197; called by muse, mutect2, varscan2
- CHEK2 | c.655G>A p.G219R (on ENST00000382580 / NM_001005735.2; = p.G176R on NM_007194.4) | Missense Mutation (SNP) | VAF 166/472 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876661085, COSV60426793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL15A1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); catalogued as rs780336096; called by muse, mutect2, varscan2
- COL17A1 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100793237; called by muse, mutect2, varscan2
- COX6A2 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 209/528 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.142); catalogued as rs941118349; called by muse, mutect2, varscan2
- CR1 | c.5218G>A p.D1740N | Missense Mutation (SNP) | VAF 133/232 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.296); catalogued as rs376980117; called by muse, mutect2, varscan2
- CSMD3 | c.4585C>T p.R1529C (on ENST00000297405 / NM_001363185.1; = p.R1425C on NM_052900.3) | Missense Mutation (SNP) | VAF 249/481 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs559167259, COSV52316014; called by muse, mutect2, varscan2
- DCLRE1A | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 131/216 reads (61%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1391696882, COSV63748207; called by muse, mutect2, varscan2
- DFFB | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 159/270 reads (59%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs372200331; called by muse, mutect2, varscan2
- DNMBP | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 160/263 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as rs267602336, COSV60621256; called by muse, mutect2, varscan2
- DRD2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 214/596 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs149926361; called by muse, mutect2
- EZR | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100454868; called by muse, mutect2, varscan2
- FAM237A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 173/442 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1210384143; called by muse, mutect2, varscan2
- FGD6 | c.3414G>A p.M1138I | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59692546; called by muse, mutect2, varscan2
- FRMPD1 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 103/178 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as COSV100899622, COSV66699159; called by muse, mutect2, varscan2
- FTCD | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 169/457 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1296829324; called by muse, mutect2, varscan2
- HYDIN | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs200044160; called by muse, mutect2, varscan2
- IGSF21 | c.1104C>T p.N368= | Splice Region (SNP) | VAF 88/158 reads (56%) | catalogued as rs775617032, COSV52138877; called by muse, mutect2, varscan2
- IKZF1 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 176/346 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); catalogued as rs773240418; called by muse, mutect2, varscan2
- IL1RL1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 138/392 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV52116318; called by muse, mutect2, varscan2
- IMPG1 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 118/335 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64059225; called by muse, mutect2, varscan2
- INSR | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 179/636 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs373196983; called by muse, mutect2, varscan2
- JAG2 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 217/593 reads (37%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as rs868746564, COSV59306555; called by muse, mutect2, varscan2
- KALRN | c.6803C>T p.S2268F (on ENST00000360013 / NM_001024660.4; = p.S571F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/248 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52255183; called by muse, mutect2, varscan2
- KIF5A | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1457616326, COSV99673482; called by muse, mutect2, varscan2
- KIR2DL3 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1313612026; called by muse, mutect2, varscan2
- L1TD1 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 168/292 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV63134301; called by muse, mutect2, varscan2
- LBR | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 367/728 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs778270986, COSV55290577; called by muse, mutect2, varscan2
- LRIT1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 145/238 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs925317349; called by muse, mutect2, varscan2
- MBOAT7 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 204/513 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1447043641, COSV99825201; called by muse, mutect2, varscan2
- MED13 | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67261837; called by muse, mutect2, varscan2
- MON1A | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 125/196 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as COSV56560675; called by muse, mutect2, varscan2
- MUC12 | c.5479G>A p.G1827R (on ENST00000379442; = p.G1684R on NM_001164462.1) | Missense Mutation (SNP) | VAF 399/774 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV65208979; called by muse, mutect2, varscan2
- MUC6 | c.4474G>A p.A1492T | Missense Mutation (SNP) | VAF 175/589 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs75068039, COSV70148636; called by muse, mutect2, varscan2
- MYO18A | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 209/491 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62872577; called by muse, mutect2, varscan2
- MYO18B | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 182/535 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122317; called by muse, mutect2
- MYO3A | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761351165, COSV56323712, COSV99780626; called by muse, mutect2, varscan2
- MYT1L | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 159/490 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV101219550, COSV67720715, COSV67731287; called by muse, mutect2, varscan2
- NRSN1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 187/540 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs557874546, COSV65893945; called by muse, varscan2
- OIT3 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 129/219 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61827249; called by muse, mutect2, varscan2
- OR2T12 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 239/870 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58776706; called by muse, mutect2, varscan2
- OR6C3 | c.464C>A p.P155Q | Missense Mutation (SNP) | VAF 202/506 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65572069; called by muse, mutect2, varscan2
- OR6C75 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 153/385 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV58553810; called by muse, mutect2, varscan2
- OR9A4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 167/587 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as COSV71885005; called by muse, mutect2, varscan2
- PACS2 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 134/397 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs145923328; called by muse, mutect2, varscan2
- PLEC | c.12598G>A p.V4200M (on ENST00000322810 / NM_201380.4; = p.V4090M on NM_000445.5) | Missense Mutation (SNP) | VAF 78/597 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201051109; called by muse, mutect2, varscan2
- PLXNA4 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 198/693 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58116096, COSV58157483; called by muse, mutect2, varscan2
- PRUNE2 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 198/321 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758162896; called by muse, mutect2, varscan2
- PSTPIP1 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 164/464 reads (35%) | catalogued as COSV51198072; called by muse, mutect2, varscan2
- PTPRS | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 244/829 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53637588; called by muse, mutect2, varscan2
- PTPRT | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs568484928, COSV61963207, COSV61977654; called by muse, mutect2, varscan2
- RABAC1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 171/430 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1480125975; called by muse, mutect2, varscan2
- RASSF5 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs369222315; called by muse, mutect2, varscan2
- S100A7 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 134/531 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV64193265; called by muse, mutect2, varscan2
- SBF2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as COSV99812930; called by muse, varscan2
- SC5D | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as rs757650933, COSV50612648; called by muse, mutect2, varscan2
- SEC31A | c.3049C>T p.P1017S (on ENST00000355196 / NM_001318120.1; = p.P978S on NM_016211.4) | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760614278; called by muse, mutect2, varscan2
- SENP1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 177/519 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973045396, COSV50301618, COSV99137080; called by muse, mutect2, varscan2
- SH3BGRL | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 91/135 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753066745, COSV64621887; called by muse, mutect2, varscan2
- SH3TC1 | c.3754-1G>A p.X1252_splice | Splice Site (SNP) | VAF 146/346 reads (42%) | catalogued as rs201476355; called by muse, mutect2, varscan2
- SHANK1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV53245463; called by muse, mutect2, varscan2
- SLC5A11 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 179/467 reads (38%) | catalogued as rs997867392, COSV61740905; called by muse, mutect2, varscan2
- SLITRK1 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 350/663 reads (53%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.776); catalogued as rs1430386168, COSV65677309; called by muse, mutect2, varscan2
- SNTG2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 167/446 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV57977418; called by muse, mutect2, varscan2
- SPOCK1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 152/235 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs760058043, COSV56438426, COSV99968145; called by muse, mutect2, varscan2
- SRBD1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55404197; called by muse, mutect2, varscan2
- STK31 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs754274194, COSV63455807; called by muse, mutect2, varscan2
- STK31 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 118/615 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs865804236; called by muse, mutect2, varscan2
- STK31 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 81/341 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV63455699; called by muse, mutect2, varscan2
- TMEM132E | c.1169C>T p.S390F (on ENST00000321639; = p.S480F on NM_001304438.2) | Missense Mutation (SNP) | VAF 151/409 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV58695194, COSV58700681; called by muse, mutect2, varscan2
- TRIM42 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 172/292 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs763391261, COSV53881671; called by muse, mutect2, varscan2
- TRPC4 | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 341/622 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59018110; called by muse, mutect2, varscan2
- TTC7B | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 133/336 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs374158727; called by muse, varscan2
- TTN | c.33013C>T p.P11005S (on ENST00000591111; = p.P10078S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/350 reads (37%) | PolyPhen benign (0); catalogued as COSV100617700; called by muse, mutect2, varscan2
- TTN | c.16805C>T p.P5602L (on ENST00000591111; = p.P4675L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/251 reads (31%) | PolyPhen probably damaging (0.999); catalogued as rs1275881697; called by muse, mutect2, varscan2
- UGT3A1 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57104324; called by muse, mutect2, varscan2
- ZNF592 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 221/580 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV55438918; called by muse, mutect2
- ZNF716 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 314/619 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1458726214, COSV70779767, COSV70781362; called by muse, mutect2
- ZNF723 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs1249507213; called by muse, mutect2, varscan2
- ABCC12 | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 165/416 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ABTB1 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 141/241 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AC013489.1 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 155/448 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- AC099489.1 | c.6282G>A p.M2094I | Missense Mutation (SNP) | VAF 157/420 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAM30 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 191/306 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANKRD36C | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 66/561 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.139); called by muse, varscan2
- ANO3 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 144/427 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AP1G2 | c.586A>T p.I196F | Missense Mutation (SNP) | VAF 138/366 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARHGAP22 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 255/435 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARID1B | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 232/625 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, varscan2
- ASCL2 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 229/577 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ATG9B | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 288/560 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCORL1 | c.2204del p.N735Tfs*48 | Frame Shift Del (DEL) | VAF 184/360 reads (51%) | called by pindel, varscan2
- BTG2 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 307/528 reads (58%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QTNF9 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6orf163 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 85/289 reads (29%) | called by muse, mutect2, varscan2
- CACNA1I | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 198/506 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNB4 | c.1012T>A p.S338T | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CARNS1 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 219/552 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASP12 | c.369G>A p.G123= | Splice Region (SNP) | VAF 134/389 reads (34%) | called by muse, mutect2, varscan2
- CAVIN2 | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CD163L1 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 138/382 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP131 | c.2099C>A p.T700N (on ENST00000269392 / NM_001319228.2; = p.T697N on NM_014984.4) | Missense Mutation (SNP) | VAF 117/372 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- CEP152 | c.4723C>T p.P1575S (on ENST00000380950 / NM_001194998.2; = p.P1519S on NM_014985.4) | Missense Mutation (SNP) | VAF 188/528 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP170B | c.2269G>T p.G757C (on ENST00000453495; = p.G686C on NM_015005.3) | Missense Mutation (SNP) | VAF 210/556 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CHRM2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 176/672 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHRNA6 | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 91/418 reads (22%) | called by muse, mutect2, varscan2
- CLMP | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- COL3A1 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CREB3L1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.10867C>T p.P3623S (on ENST00000297405 / NM_001363185.1; = p.P3454S on NM_052900.3) | Missense Mutation (SNP) | VAF 250/476 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- CYP3A4 | c.141G>T p.L47F | Missense Mutation (SNP) | VAF 170/336 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- DDX54 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 204/564 reads (36%) | called by muse, mutect2, varscan2
- DSCAM | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 150/436 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSP | c.6713C>T p.S2238F | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- EXOC1 | c.2218C>T p.L740F | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FCAMR | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 178/608 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FLG2 | c.6229G>A p.G2077R | Missense Mutation (SNP) | VAF 170/688 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRYL | c.4607C>T p.S1536F | Missense Mutation (SNP) | VAF 121/426 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRG1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLT6D1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 131/190 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR158 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 149/411 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR158 | c.1458G>T p.W486C | Missense Mutation (SNP) | VAF 136/400 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-F | c.785T>A p.F262Y | Missense Mutation (SNP) | VAF 210/592 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- HOXD3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 224/737 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYAL3 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 227/369 reads (62%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- IDE | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 99/164 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- IGHG3 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 195/547 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH7 | c.2587T>A p.F863I | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KRT75 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 241/611 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGR6 | c.247C>T p.P83S (on ENST00000367278 / NM_001017403.1; = p.P31S on NM_021636.3) | Missense Mutation (SNP) | VAF 214/400 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- LILRA2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 147/448 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- LZTS1 | c.1624T>C p.Y542H | Missense Mutation (SNP) | VAF 191/716 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA4 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 216/282 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1S | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MGAM2 | c.693C>A p.H231Q | Missense Mutation (SNP) | VAF 78/554 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MGAT5B | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- MMP13 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MTRNR2L6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 234/426 reads (55%) | PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MTX2 | c.178A>T p.R60W | Missense Mutation (SNP) | VAF 211/372 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEFL | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 353/676 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NKAP | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 96/136 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP1 | c.3645G>T p.L1215F | Missense Mutation (SNP) | VAF 227/593 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- NOD2 | c.3035C>T p.T1012I | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NPM1 | c.141C>T p.V47= | Splice Region (SNP) | VAF 93/235 reads (40%) | called by muse, mutect2, varscan2
- NYNRIN | c.5285C>T p.T1762I | Missense Mutation (SNP) | VAF 195/555 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OBSCN | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 211/773 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4D9 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 141/442 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR51A2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- OR51Q1 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- PGR | c.1914A>T p.K638N | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PKP4 | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 158/414 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PMFBP1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 190/530 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POGZ | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 141/475 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POSTN | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 86/333 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- POU3F3 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 215/569 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PRKCB | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PRSS38 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 211/798 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCHD3 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 220/525 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRD | c.4499T>C p.L1500P | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRN | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX4 | c.1405G>A p.E469K (on ENST00000392842 / NM_213594.3; = p.E375K on NM_032491.6) | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RGL4 | c.80G>A p.W27* | Nonsense Mutation (SNP) | VAF 233/560 reads (42%) | called by muse, mutect2, varscan2
- RHOXF2 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- RHOXF2B | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 272/354 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RNF126 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 224/553 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- RNFT2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 136/345 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- RPL13A | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- RTL3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 183/239 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SAFB2 | c.1161A>T p.E387D | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SATB2 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 194/514 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SLC2A9 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- SLC39A2 | c.817A>C p.T273P | Missense Mutation (SNP) | VAF 176/488 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A8 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT tolerated (0.96); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- STAB2 | c.4601G>A p.G1534E | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAG1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 101/162 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STON1 | c.1388T>A p.L463* | Nonsense Mutation (SNP) | VAF 131/358 reads (37%) | called by muse, mutect2, varscan2
- SULT6B1 | c.538G>A p.G180R (on ENST00000535679 / NM_001367551.1; = p.G142R on NM_001032377.2) | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAB3 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 148/208 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- TARBP1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 353/663 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TARM1 | c.442G>A p.G148R (on ENST00000616041 / NM_001330650.1; = p.G140R on NM_001135686.3) | Missense Mutation (SNP) | VAF 245/663 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAS2R10 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D32 | c.2772A>G p.Q924= | Splice Region (SNP) | VAF 67/218 reads (31%) | called by muse, mutect2, varscan2
- TDRD15 | c.4315G>A p.V1439I | Missense Mutation (SNP) | VAF 119/299 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM74 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 182/641 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TTN | c.99677A>T p.E33226V (on ENST00000591111; = p.E25802V on NM_003319.4) | Missense Mutation (SNP) | VAF 212/527 reads (40%) | PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TTN | c.9175G>A p.E3059K (on ENST00000591111; = p.E3013K on NM_003319.4) | Missense Mutation (SNP) | VAF 85/266 reads (32%) | PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UBE3A | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP30 | c.666T>A p.H222Q | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- USP6 | c.3847G>T p.D1283Y | Missense Mutation (SNP) | VAF 180/481 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- VIPAS39 | c.854A>C p.E285A | Missense Mutation (SNP) | VAF 125/347 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- VWDE | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 107/490 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- XDH | c.849G>A p.W283* | Nonsense Mutation (SNP) | VAF 130/378 reads (34%) | called by muse, mutect2, varscan2
- YBX1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 164/282 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF354A | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 132/222 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF469 | c.10634G>A p.G3545E (on ENST00000437464; = p.G3573E on NM_001367624.2) | Missense Mutation (SNP) | VAF 232/637 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF541 | c.3016G>A p.G1006S | Missense Mutation (SNP) | VAF 230/546 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAP2 | c.297C>T p.I99= | Silent (SNP) | VAF 144/421 reads (34%) | called by muse, mutect2, varscan2
- AGBL3 | c.1128C>T p.G376= | Silent (SNP) | VAF 170/599 reads (28%) | called by muse, mutect2, varscan2
- AOX1 | c.627A>G p.P209= | Silent (SNP) | VAF 138/363 reads (38%) | catalogued as rs763279070; called by muse, mutect2, varscan2
- APOB | c.11607C>T p.F3869= | Silent (SNP) | VAF 149/408 reads (37%) | catalogued as COSV51942607, COSV51954942; called by muse, mutect2, varscan2
- ARHGAP45 | c.597G>A p.E199= | Silent (SNP) | VAF 132/310 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.918G>A p.R306= | Silent (SNP) | VAF 117/368 reads (32%) | catalogued as rs200436029; called by muse, mutect2, varscan2
- ARHGAP45 | c.957G>A p.K319= | Silent (SNP) | VAF 158/471 reads (34%) | called by muse, mutect2, varscan2
- B4GALNT3 | c.843C>T p.S281= | Silent (SNP) | VAF 164/414 reads (40%) | catalogued as rs370374991; called by muse, mutect2, varscan2
- BARX2 | c.636C>T p.I212= | Silent (SNP) | VAF 163/457 reads (36%) | catalogued as rs867494584; called by muse, mutect2, varscan2
- BASP1 | c.357C>T p.A119= | Silent (SNP) | VAF 182/300 reads (61%) | called by muse, mutect2, varscan2
- BEND2 | c.528G>A p.Q176= | Silent (SNP) | VAF 171/240 reads (71%) | called by muse, mutect2, varscan2
- C10orf71 | c.3942C>T p.S1314= | Silent (SNP) | VAF 213/333 reads (64%) | called by muse, mutect2, varscan2
- CACNG6 | c.507C>T p.F169= | Silent (SNP) | VAF 163/416 reads (39%) | catalogued as rs866884515, COSV53167402; called by muse, mutect2, varscan2
- CCDC166 | c.1080C>T p.S360= | Silent (SNP) | VAF 265/949 reads (28%) | called by muse, mutect2, varscan2
- CELSR2 | c.1707C>T p.D569= | Silent (SNP) | VAF 184/296 reads (62%) | catalogued as rs1180517683; called by muse, mutect2, varscan2
- CEP131 | c.2601G>A p.Q867= (on ENST00000269392 / NM_001319228.2; = p.Q864= on NM_014984.4) | Silent (SNP) | VAF 156/450 reads (35%) | catalogued as rs1319238403; called by muse, mutect2, varscan2
- CFAP97D1 | c.309C>T p.S103= | Silent (SNP) | VAF 120/291 reads (41%) | called by muse, mutect2, varscan2
- CILP2 | c.2697C>T p.F899= | Silent (SNP) | VAF 237/825 reads (29%) | catalogued as rs572861829, COSV52277913; called by muse, mutect2, varscan2
- CLC | c.228G>A p.V76= | Silent (SNP) | VAF 178/470 reads (38%) | catalogued as COSV99695550; called by muse, mutect2, varscan2
- CPXM1 | c.2094C>T p.F698= | Silent (SNP) | VAF 124/353 reads (35%) | catalogued as rs766761505, COSV66044544; called by muse, mutect2, varscan2
- CR1L | c.1290C>T p.I430= | Silent (SNP) | VAF 137/582 reads (24%) | called by muse, mutect2, varscan2
- CREB5 | c.189G>A p.T63= (on ENST00000357727 / NM_182898.4; = p.T56= on NM_004904.3) | Silent (SNP) | VAF 114/477 reads (24%) | catalogued as rs767456309, COSV63217940; called by muse, mutect2, varscan2
- CTNND2 | c.2940C>T p.A980= | Silent (SNP) | VAF 165/269 reads (61%) | catalogued as rs534391683, COSV58918821; called by muse, mutect2, varscan2
- CYP1A2 | c.1068G>A p.R356= | Silent (SNP) | VAF 71/266 reads (27%) | catalogued as COSV59660545; called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1548C>T p.F516= | Silent (SNP) | VAF 133/535 reads (25%) | called by muse, mutect2, varscan2
- DCC | c.3348C>T p.I1116= | Silent (SNP) | VAF 143/407 reads (35%) | catalogued as rs1474376680, COSV71426219; called by muse, mutect2, varscan2
- EDC3 | c.351C>T p.I117= | Silent (SNP) | VAF 162/461 reads (35%) | catalogued as COSV59340084; called by muse, mutect2, varscan2
- EGFR | c.2463C>T p.I821= | Silent (SNP) | VAF 102/408 reads (25%) | catalogued as rs367859869; called by muse, mutect2, varscan2
- ENOSF1 | c.261C>T p.V87= (on ENST00000340116 / NM_001354066.2; = p.V39= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 124/327 reads (38%) | catalogued as rs139918997; called by muse, mutect2, varscan2
- FECH | c.498C>T p.V166= | Silent (SNP) | VAF 147/372 reads (40%) | called by muse, mutect2, varscan2
- GALNT16 | c.1488C>T p.S496= | Silent (SNP) | VAF 176/529 reads (33%) | catalogued as rs866343413; called by muse, mutect2, varscan2
- GRM5 | c.2085G>A p.V695= | Silent (SNP) | VAF 179/472 reads (38%) | catalogued as COSV59594499; called by muse, mutect2, varscan2
- GRM8 | c.867G>A p.R289= | Silent (SNP) | VAF 113/393 reads (29%) | catalogued as COSV58802860; called by muse, mutect2, varscan2
- GUCY1A2 | c.1464G>A p.K488= | Silent (SNP) | VAF 138/409 reads (34%) | catalogued as COSV56492377; called by muse, mutect2, varscan2
- HGFAC | c.1659C>T p.S553= | Silent (SNP) | VAF 125/331 reads (38%) | catalogued as COSV66977327; called by muse, varscan2
- HGFAC | c.1660C>T p.L554= | Silent (SNP) | VAF 124/334 reads (37%) | called by muse, varscan2
- HIBADH | c.729C>T p.I243= | Silent (SNP) | VAF 150/562 reads (27%) | catalogued as COSV55315881; called by muse, mutect2, varscan2
- INSR | c.1422A>G p.G474= | Silent (SNP) | VAF 204/671 reads (30%) | catalogued as COSV57157606; called by muse, mutect2, varscan2
- INSR | c.300G>A p.K100= | Silent (SNP) | VAF 179/637 reads (28%) | catalogued as rs1472828248; called by muse, mutect2, varscan2
- ITIH5 | c.2064C>T p.F688= | Silent (SNP) | VAF 150/400 reads (38%) | catalogued as rs150070433, COSV53672701; called by muse, mutect2, varscan2
- IVL | c.705C>T p.L235= | Silent (SNP) | VAF 154/991 reads (16%) | catalogued as COSV64216892; called by muse, varscan2
- KCNB2 | c.117C>T p.I39= | Silent (SNP) | VAF 379/679 reads (56%) | catalogued as COSV73052538; called by muse, mutect2, varscan2
- KCNG1 | c.1401C>T p.Y467= | Silent (SNP) | VAF 35/1141 reads (3%) | called by muse, mutect2
- KCNH6 | c.2052G>A p.K684= | Silent (SNP) | VAF 206/603 reads (34%) | catalogued as COSV59001137, COSV59007430; called by muse, mutect2, varscan2
- KCNK5 | c.1392C>T p.F464= | Silent (SNP) | VAF 171/492 reads (35%) | catalogued as COSV63989069; called by muse, mutect2, varscan2
- KCNK5 | c.1023G>A p.L341= | Silent (SNP) | VAF 210/566 reads (37%) | catalogued as rs1345529611; called by muse, mutect2, varscan2
- KHDC1 | c.234G>A p.T78= (on ENST00000370384 / NM_001251874.2; = p.T5= on NM_030568.5) | Silent (SNP) | VAF 75/218 reads (34%) | catalogued as rs771392349; called by muse, mutect2, varscan2
- LHFPL3 | c.435C>T p.F145= | Silent (SNP) | VAF 120/498 reads (24%) | catalogued as COSV67810773; called by muse, mutect2, varscan2
- LRRC8B | c.1473C>T p.I491= | Silent (SNP) | VAF 136/216 reads (63%) | called by muse, mutect2, varscan2
- MAGEA12 | c.627C>T p.I209= | Silent (SNP) | VAF 231/309 reads (75%) | catalogued as rs1556833541, COSV100757111; called by muse, mutect2, varscan2
- MEFV | c.1938G>A p.P646= | Silent (SNP) | VAF 164/461 reads (36%) | catalogued as rs104895160; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEN1 | c.1290G>A p.E430= | Silent (SNP) | VAF 170/477 reads (36%) | catalogued as rs1236745071; called by muse, mutect2, varscan2
- METTL2A | c.693T>C p.S231= | Silent (SNP) | VAF 155/514 reads (30%) | called by muse, mutect2, varscan2
- MRPS7 | c.343C>T p.L115= | Silent (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- MS4A4E | c.117C>T p.F39= | Silent (SNP) | VAF 93/267 reads (35%) | catalogued as rs1376683455, COSV101301579; called by muse, mutect2, varscan2
- MSLN | c.645G>A p.L215= | Silent (SNP) | VAF 165/489 reads (34%) | called by muse, mutect2, varscan2
- MUC15 | c.792G>A p.R264= | Silent (SNP) | VAF 177/449 reads (39%) | catalogued as COSV55553092; called by muse, mutect2, varscan2
- MUC16 | c.9093C>A p.P3031= | Silent (SNP) | VAF 129/504 reads (26%) | called by muse, mutect2, varscan2
- NLRC5 | c.5502C>T p.N1834= | Silent (SNP) | VAF 138/360 reads (38%) | called by muse, mutect2, varscan2
- NME8 | c.249A>G p.E83= | Silent (SNP) | VAF 206/307 reads (67%) | catalogued as rs777289980; called by muse, mutect2, varscan2
- NOC2L | c.510C>T p.F170= | Silent (SNP) | VAF 120/204 reads (59%) | called by muse, varscan2
- ODF1 | c.660C>A p.P220= | Silent (SNP) | VAF 228/848 reads (27%) | catalogued as rs776206902, COSV53433116; called by muse, mutect2
- OR2A2 | c.823C>T p.L275= | Silent (SNP) | VAF 165/568 reads (29%) | catalogued as rs753114056, COSV101286686, COSV68872232; called by muse, mutect2, varscan2
- OR4E1 | c.108C>T p.L36= | Silent (SNP) | VAF 172/457 reads (38%) | called by muse, mutect2, varscan2
- OR8D2 | c.849C>A p.P283= | Silent (SNP) | VAF 72/398 reads (18%) | catalogued as rs897466353; called by muse, mutect2, varscan2
- PCDH18 | c.2862C>T p.F954= | Silent (SNP) | VAF 162/453 reads (36%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1485G>A p.V495= | Silent (SNP) | VAF 309/487 reads (63%) | catalogued as COSV63544439; called by muse, mutect2, varscan2
- PDILT | c.525C>T p.V175= | Silent (SNP) | VAF 141/373 reads (38%) | called by muse, mutect2, varscan2
- PERM1 | c.2145G>A p.R715= | Silent (SNP) | VAF 137/223 reads (61%) | called by muse, mutect2, varscan2
- PORCN | c.495C>T p.I165= | Silent (SNP) | VAF 219/288 reads (76%) | catalogued as rs782039537; called by muse, mutect2, varscan2
- PRKCQ | c.1608G>A p.T536= | Silent (SNP) | VAF 118/359 reads (33%) | catalogued as rs751782966, COSV54107032; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1902G>A p.E634= | Silent (SNP) | VAF 95/316 reads (30%) | catalogued as rs1017947882; called by muse, mutect2, varscan2
- RFX4 | c.1257C>T p.S419= (on ENST00000392842 / NM_213594.3; = p.S325= on NM_032491.6) | Silent (SNP) | VAF 136/391 reads (35%) | called by muse, mutect2, varscan2
- RHBG | c.520C>T p.L174= | Silent (SNP) | VAF 176/342 reads (51%) | catalogued as COSV99659575; called by muse, varscan2
- ROS1 | c.5355C>T p.I1785= | Silent (SNP) | VAF 66/225 reads (29%) | catalogued as COSV63860752; called by muse, mutect2, varscan2
- RP1L1 | c.1710G>A p.E570= | Silent (SNP) | VAF 211/765 reads (28%) | called by muse, mutect2, varscan2
- SCN11A | c.4431C>T p.V1477= | Silent (SNP) | VAF 191/300 reads (64%) | called by muse, mutect2, varscan2
- SERPINA6 | c.798C>T p.I266= | Silent (SNP) | VAF 211/618 reads (34%) | catalogued as COSV100448382; called by muse, mutect2, varscan2
- SHC3 | c.690C>T p.S230= | Silent (SNP) | VAF 119/187 reads (64%) | catalogued as COSV65439609; called by muse, mutect2, varscan2
- SIN3B | c.1416C>T p.F472= | Silent (SNP) | VAF 173/440 reads (39%) | catalogued as rs369985112; called by muse, mutect2, varscan2
- SIRPB1 | c.450C>T p.P150= | Silent (SNP) | VAF 140/414 reads (34%) | catalogued as rs746821087; called by muse, mutect2, varscan2
- SLC39A5 | c.348G>A p.G116= | Silent (SNP) | VAF 202/523 reads (39%) | catalogued as rs759554965; called by muse, mutect2, varscan2
- SLFN5 | c.1962C>T p.F654= | Silent (SNP) | VAF 132/383 reads (34%) | catalogued as rs999971549; called by muse, mutect2, varscan2
- SMARCA4 | c.3639G>A p.K1213= | Silent (SNP) | VAF 128/550 reads (23%) | catalogued as COSV60789910; called by muse, mutect2, varscan2
- SORCS2 | c.2379C>T p.A793= | Silent (SNP) | VAF 223/587 reads (38%) | catalogued as rs561816984; called by muse, mutect2, varscan2
- SPATA31E1 | c.1974G>A p.G658= | Silent (SNP) | VAF 182/305 reads (60%) | called by muse, mutect2, varscan2
- STYXL2 | c.816G>A p.R272= | Silent (SNP) | VAF 166/663 reads (25%) | catalogued as COSV99609653; called by muse, mutect2, varscan2
- TDRD12 | c.1411C>T p.L471= | Silent (SNP) | VAF 166/471 reads (35%) | called by muse, mutect2, varscan2
- TDRD15 | c.1293C>T p.S431= | Silent (SNP) | VAF 115/345 reads (33%) | called by muse, mutect2, varscan2
- TGM6 | c.633C>T p.R211= | Silent (SNP) | VAF 159/404 reads (39%) | called by muse, mutect2, varscan2
- TMEM177 | c.846C>T p.H282= | Silent (SNP) | VAF 169/452 reads (37%) | called by muse, mutect2, varscan2
- TNRC18 | c.8797C>T p.L2933= | Silent (SNP) | VAF 162/549 reads (30%) | catalogued as rs778666455; called by muse, mutect2, varscan2
- TRAV18 | c.243G>A p.Q81= | Silent (SNP) | VAF 152/403 reads (38%) | called by muse, mutect2, varscan2
- TRGV10 | c.204C>T p.V68= | Silent (SNP) | VAF 135/550 reads (25%) | called by muse, mutect2, varscan2
- USP18 | c.669A>T p.S223= | Silent (SNP) | VAF 156/437 reads (36%) | called by muse, mutect2, varscan2
- WDR87 | c.2466C>T p.F822= | Silent (SNP) | VAF 148/452 reads (33%) | catalogued as rs541048109, COSV58201882; called by muse, mutect2, varscan2
- ZNF14 | c.1347T>C p.C449= | Silent (SNP) | VAF 169/657 reads (26%) | called by muse, mutect2, varscan2
- ZNF236 | c.5085C>T p.F1695= | Silent (SNP) | VAF 146/403 reads (36%) | called by muse, mutect2, varscan2
- ZNF275 | c.654C>T p.F218= | Silent (SNP) | VAF 164/208 reads (79%) | catalogued as COSV100936175; called by muse, mutect2, varscan2
- ZNF514 | c.888C>T p.A296= | Silent (SNP) | VAF 161/442 reads (36%) | called by muse, mutect2, varscan2
- ZNF728 | c.759G>A p.E253= | Silent (SNP) | VAF 123/336 reads (37%) | catalogued as COSV74099456, COSV74099652, COSV74099716; called by muse, mutect2, varscan2
- ZNF85 | c.117C>T p.N39= | Silent (SNP) | VAF 61/278 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915742 C>T | 5'Flank (SNP) | VAF 201/565 reads (36%) | catalogued as rs1559036771; called by muse, mutect2, varscan2
- CCKBR | c.151+4426G>A | Intron (SNP) | VAF 130/384 reads (34%) | catalogued as rs1383464872; called by muse, mutect2, varscan2
- CCM2 | c.31-10482C>T | Intron (SNP) | VAF 260/502 reads (52%) | called by muse, mutect2, varscan2
- DCHS2 | n.3855G>A | RNA (SNP) | VAF 143/366 reads (39%) | catalogued as rs1309994602, COSV61771238; called by muse, mutect2, varscan2
- DOK3 | c.-79G>A | 5'UTR (SNP) | VAF 128/386 reads (33%) | called by muse, mutect2, varscan2
- IFNL4 | c.422+296G>A | Intron (SNP) | VAF 181/480 reads (38%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+911C>T | Intron (SNP) | VAF 170/574 reads (30%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1448G>A | Intron (SNP) | VAF 374/673 reads (56%) | catalogued as rs1377736023; called by muse, mutect2, varscan2
- ITGA2 | c.*217C>T | 3'UTR (SNP) | VAF 60/161 reads (37%) | catalogued as rs1314181195; called by muse, mutect2, varscan2
- PCDHA8 | c.2394+42G>A | Intron (SNP) | VAF 108/212 reads (51%) | called by muse, mutect2, varscan2
- PEG10 | c.*38C>T | 3'UTR (SNP) | VAF 334/603 reads (55%) | called by muse, mutect2, varscan2
- RAI14 | c.36+1267C>T | Intron (SNP) | VAF 123/202 reads (61%) | catalogued as rs1032858317; called by muse, mutect2, varscan2
- TMEM105 | n.732C>T | RNA (SNP) | VAF 212/562 reads (38%) | catalogued as COSV59654873; called by muse, mutect2, varscan2
- TTN | c.10360+1679G>A | Intron (SNP) | VAF 129/327 reads (39%) | catalogued as COSV59890486, COSV60044690; called by muse, mutect2, varscan2
